MMRF case MMRF_2063 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3a71752b-c040-4dc2-b3e2-fd5e5bb92f9d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Dead; Days to death: 46 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.4 years (24,615 days); ISS stage: III; Days to last known disease status: 46 days; Days to last follow up: 46 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 46 days.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -28, day 46.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Platelets 108 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Lambda 95.5 mg/dL.
- Absolute Neutrophil 1.7 ×10⁹/L.
- Immunoglobulin G 1.99 g/L.
- Calcium 2.33 mmol/L.
- Hemoglobin 6.76 mmol/L.
- Lactate Dehydrogenase 1.73 µkat/L.
- Glucose 5.28 mmol/L.
- Immunoglobulin A 98.1 g/L.
- Creatinine 106 µmol/L.
- Total Protein 12.4 g/dL.
- Immunoglobulin M 0.1 g/L.
- Serum Free Immunoglobulin Light Chain, Kappa 0.32 mg/dL.
- Beta 2 Microglobulin 12.3 µg/mL.
- Leukocytes 4 ×10⁹/L.
- Albumin 30 g/L.
- M Protein 7.1 g/dL.

Other clinical attributes
- Day -28: Weight: 150 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2063_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -28 days.
- Sample MMRF_2063_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -28 days.
